Somatic mutation profile of tumor specimen TCGA-24-2293-01A (aliquot TCGA-24-2293-01A-01W-0799-08) from TCGA case TCGA-24-2293, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Specified parts of peritoneum; Tumor grade: G3; Age at diagnosis: 47.2 years (17,235 days).
Specimen TCGA-24-2293-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 723ed100-a92d-46dc-b724-73d808ca55ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2293-10A (Blood Derived Normal), aliquot TCGA-24-2293-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9d3e0db-7f26-4cef-b40a-df64cd4873ae

The open-access MAF lists 84 somatic variants for this specimen: 69 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 13, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 2, Splice Region 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 60/164 reads (37%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAM19 | c.2117G>T p.G706V | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as COSV57431242, COSV99976463; called by muse, mutect2
- ADAMTS19 | c.2710A>G p.T904A | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV99176574; called by muse, mutect2, varscan2
- AFF2 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as rs782117157, COSV53991890; called by muse, mutect2, varscan2
- AFF4 | c.2063T>A p.F688Y | Missense Mutation (SNP) | VAF 11/271 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.228); catalogued as COSV99534690; called by muse, mutect2
- ANO2 | c.2254G>T p.V752F (on ENST00000356134 / NM_001278597.3; = p.V756F on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100500095; called by muse, mutect2
- ARHGAP26 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 59/742 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99189628; called by muse, mutect2
- ATXN1 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV99785550; called by muse, mutect2
- BRIP1 | c.1949C>T p.T650I | Missense Mutation (SNP) | VAF 128/310 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52000552; called by muse, mutect2, varscan2
- BRWD3 | c.3701T>G p.V1234G | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64748951; called by muse, mutect2, varscan2
- C1orf53 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 62/1233 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV100956406, COSV66323459; called by muse, mutect2
- CASP5 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 64/392 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs761988172, COSV52828789, COSV52829027; called by muse, mutect2
- CELSR2 | c.1471G>C p.V491L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.928); catalogued as COSV54773099; called by muse, mutect2, varscan2
- CRY1 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99150489; called by muse, mutect2
- DMXL1 | c.1201C>A p.H401N | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as COSV100223519; called by muse, mutect2
- DNAJA3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52162152; called by muse, mutect2, varscan2
- DPAGT1 | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV62614538; called by muse, mutect2, varscan2
- EPS8 | c.721G>C p.A241P | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.65); catalogued as COSV55531504; called by muse, mutect2, varscan2
- FAM217B | c.847A>T p.R283W | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV62564466; called by muse, mutect2, varscan2
- FREM1 | c.1483G>C p.V495L | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV66518193, COSV66524573; called by muse, mutect2, varscan2
- GRB14 | c.200A>T p.K67M | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV55738684; called by muse, mutect2, varscan2
- IMPDH1 | c.608G>T p.S203I (on ENST00000470772 / NM_001142573.2; = p.S289I on NM_000883.4) | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV100118624; called by muse, mutect2
- JAZF1 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 17/333 reads (5%) | catalogued as COSV99386193; called by muse, mutect2
- KAT14 | c.1990G>C p.D664H | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66607926; called by muse, mutect2, varscan2
- KCNH7 | c.2054A>G p.E685G | Missense Mutation (SNP) | VAF 79/507 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59798719; called by muse, mutect2, varscan2
- KDM4C | c.2352A>T p.E784D | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV67187218; called by muse, mutect2, varscan2
- KIF21A | c.2203C>T p.L735F (on ENST00000361418 / NM_001378440.1; = p.L722F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62772218; called by muse, mutect2, varscan2
- KRTAP24-1 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs371296443; called by muse, mutect2, varscan2
- LCOR | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 90/403 reads (22%) | catalogued as COSV100603541; called by muse, mutect2, varscan2
- MAGEC1 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 63/634 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99595131; called by muse, varscan2
- MAML2 | c.2003C>A p.S668Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV101594059; called by muse, mutect2, varscan2
- MATN1 | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101056213; called by muse, mutect2
- MCAT | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99295610; called by muse, mutect2
- MINAR1 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs147416682; called by muse, mutect2, varscan2
- MTF2 | c.481A>C p.K161Q | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV64770675; called by muse, mutect2, varscan2
- MUC16 | c.37680C>A p.D12560E | Missense Mutation (SNP) | VAF 1194/2664 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.583); catalogued as COSV67470247; called by muse, mutect2, varscan2
- MYBBP1A | c.3435-1G>T p.X1145_splice | Splice Site (SNP) | VAF 6/84 reads (7%) | catalogued as COSV99625557; called by muse, mutect2
- MYBPC2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV63096193; called by muse, mutect2
- NAA10 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100603908; called by muse, mutect2
- NEUROD6 | c.602G>T p.R201M | Missense Mutation (SNP) | VAF 25/625 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99773931; called by muse, mutect2
- NF2 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746025177, COSV58524608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR11L1 | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63314723; called by muse, mutect2, varscan2
- OR4C12 | c.568A>C p.T190P | Missense Mutation (SNP) | VAF 112/538 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58860146; called by muse, mutect2, varscan2
- PLCL1 | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 20/139 reads (14%) | catalogued as rs376872615, COSV101407230, COSV70886021; called by muse, mutect2, varscan2
- PRR11 | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV51876935; called by muse, mutect2, varscan2
- PXDNL | c.634T>C p.Y212H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV62488575; called by muse, mutect2, varscan2
- RABEP1 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99336397; called by muse, mutect2
- RAPGEF3 | c.2329C>A p.P777T (on ENST00000389212; = p.P735T on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs369346288; called by mutect2, varscan2
- SP140 | c.1563T>C p.N521= | Splice Region (SNP) | VAF 24/61 reads (39%) | catalogued as COSV59450475; called by muse, mutect2, varscan2
- SRRM1 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 26/221 reads (12%) | catalogued as COSV60477818; called by muse, mutect2, varscan2
- SSR3 | c.491+1G>A p.X164_splice | Splice Site (SNP) | VAF 8/77 reads (10%) | catalogued as rs1225778961, COSV99411003; called by muse, mutect2
- STUM | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 45/466 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV64684378; called by muse, mutect2
- TACC2 | c.7742C>A p.T2581N (on ENST00000334433; = p.T659N on NM_006997.4) | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99586774; called by muse, mutect2
- TBX15 | c.1597G>A p.E533K (on ENST00000369429 / NM_001330677.2; = p.E427K on NM_152380.3) | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV52871373; called by muse, mutect2
- TEKT3 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 107/309 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs764367004, COSV100106876; called by muse, mutect2, varscan2
- TGM2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.239); catalogued as rs546290418, COSV100821521; called by muse, mutect2
- THRAP3 | c.1926C>A p.H642Q | Missense Mutation (SNP) | VAF 191/900 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63568131; called by muse, mutect2, varscan2
- TTC33 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100531835; called by muse, mutect2
- TTN | c.76723C>T p.R25575C (on ENST00000591111; = p.R18151C on NM_003319.4) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | PolyPhen probably damaging (0.998); catalogued as rs756815015, COSV59899329; called by muse, mutect2, varscan2
- UBR4 | c.13882G>T p.V4628L | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64390930; called by muse, mutect2, varscan2
- WASHC2A | c.3113G>A p.R1038H | Missense Mutation (SNP) | VAF 138/836 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336069461, COSV50953959; called by muse, mutect2, varscan2
- WDR4 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs1261831020, COSV100375186, COSV57733849; called by muse, mutect2, varscan2
- ZNF285 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs772355334, COSV58409256; called by muse, mutect2, varscan2
- ZNF91 | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.519); catalogued as COSV56085437; called by muse, mutect2, varscan2
- ZXDB | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV66492597; called by muse, mutect2, varscan2
- CCDC66 | c.1468A>G p.K490E (on ENST00000394672 / NM_001353147.1; = p.K456E on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by mutect2, varscan2
- FAM167B | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.467); called by muse, mutect2
- SUPT20HL2 | c.1762T>A p.L588M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- THRA | c.1004_1005del p.V335Gfs*82 | Frame Shift Del (DEL) | VAF 9/71 reads (13%) | called by mutect2*, pindel
- CBL | c.1012T>C p.L338= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV50639003; called by muse, mutect2
- COL11A1 | c.3402G>A p.P1134= | Silent (SNP) | VAF 62/364 reads (17%) | catalogued as rs763588142, COSV62185009; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGFR | c.193T>C p.L65= | Silent (SNP) | VAF 27/256 reads (11%) | catalogued as COSV99288028; called by muse, mutect2
- NCOA3 | c.2043G>A p.K681= | Silent (SNP) | VAF 35/308 reads (11%) | catalogued as COSV100507275, COSV100508611; called by muse, mutect2, varscan2
- NDUFS8 | c.531C>A p.T177= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99693194; called by muse, mutect2
- OR5M3 | c.495C>T p.Y165= | Silent (SNP) | VAF 50/400 reads (13%) | called by muse, mutect2, varscan2
- PPP2R3A | c.678G>T p.G226= | Silent (SNP) | VAF 11/208 reads (5%) | catalogued as COSV99386620; called by muse, mutect2
- RABIF | c.52C>A p.R18= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs375439968; called by muse, mutect2
- SCN1A | c.3243A>T p.G1081= (on ENST00000303395 / NM_001202435.3; = p.G1070= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV57672073; called by muse, mutect2, varscan2
- SLC4A1AP | c.2184A>C p.S728= | Silent (SNP) | VAF 20/266 reads (8%) | catalogued as COSV100389220; called by muse, mutect2
- SPATA18 | c.738G>A p.E246= | Silent (SNP) | VAF 45/197 reads (23%) | catalogued as COSV54645458, COSV99730913; called by muse, mutect2, varscan2
- SUSD5 | c.1038C>T p.P346= | Silent (SNP) | VAF 48/205 reads (23%) | catalogued as COSV58878748; called by muse, mutect2, varscan2
- USP25 | c.2871C>T p.I957= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs745687485, COSV53485103, COSV99584311; called by muse, mutect2, varscan2
- BCAS4 | c.*62C>T | 3'UTR (SNP) | VAF 13/139 reads (9%) | catalogued as rs755111655, COSV52811861; called by muse, mutect2
- NUDCD3 | c.509+16848C>T | Intron (SNP) | VAF 131/467 reads (28%) | catalogued as rs549739690; called by muse, mutect2, varscan2
